Somatic mutation profile of tumor specimen 0DD0A7 from CCDI case PBBMYX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.2 years (805 days).
Specimen 0DD0A7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5b49b98a-67a0-4181-a50b-43cd23b79acd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DD09I (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c7aeddd-7b1c-4ab9-9ac8-67726a371cb2

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, 3'UTR 1, Intron 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 520/1336 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CARD11 | c.2009C>T p.T670M | Missense Mutation (SNP) | VAF 294/856 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs3735134, COSV62754906; called by muse, mutect2, varscan2
- MYH9 | c.490+1G>A p.X164_splice | Splice Site (SNP) | VAF 328/1049 reads (31%) | called by muse, mutect2, varscan2
- STING1 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 306/905 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- HERC1 | c.13689-37G>T | Intron (SNP) | VAF 8/234 reads (3%) | called by muse, mutect2
- IL17D | c.*47C>T | 3'UTR (SNP) | VAF 54/150 reads (36%) | called by muse, mutect2, varscan2
- PGDP1 | n.425C>T | RNA (SNP) | VAF 175/488 reads (36%) | catalogued as rs757974878; called by muse, mutect2
